Surgical pathology report (de-identified scan), TCGA case TCGA-DU-8165, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-8165-01A (Primary Tumor).

[page 1 of 6]
Surgical Pathology Report

Patient Name: [REDACTED]

Accession #: [REDACTED]

Med: Rec.: [REDACTED]

Phone Number: [REDACTED]

DOB: [REDACTED]

Gender: F

Client: [REDACTED]

Location: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

=====

CLINICAL HISTORY

[REDACTED] woman experienced recent onset seizure, and on imaging has a

1.5 cm, left anterior temporal lobe lesion with cystic component and peripheral enhancement.

OPERATIVE DIAGNOSES

Possible brain tumor left temporal lobe

Operation/Specimen: A: Brain tumor, biopsy

PATHOLOGICAL DIAGNOSIS:

Brain, site not specified, excisional biopsy: Anaplastic oligodendroglioma.

See Microscopy Description and Comment.

COMMENT

The sections contain portions of cerebrum that are heavily infiltrated/effaced by a neoplastic proliferation of glial cells that have astrocyte-like phenotype, but with rather uniform round nuclei and frequently with perinuclear halos. There is brisk mitotic activity, with a high MIB-1 proliferation index of about 30%. There is prominent endothelial hyperplasia, and focal microvascular cellular proliferation. There is no tumor necrosis.

The features are those of an anaplastic oligodendroglioma.

Results of molecular testing are reported below.

[REDACTED]

[page 2 of 6]
PROCEDURES/ADDENDA

PCR for EGFR variant III mutation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from

H and E slide was examined and no microdissection was needed.

The epidermal growth factor receptor (EGFR) is an attractive molecular target

in glioblastoma because it is amplified, overexpressed, and/or mutated in up

to 40% to 50% of patients. Epidermal growth factor receptor variant III

(EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is

commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct

subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been

shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor

suppressor protein PTEN is intact. RNA is extracted from formalin fixed,

paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is

then amplified using standard PCR technique for DNA templates. PCR products

are detected by gel electrophoresis. The limit of detection of this assay has

been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by CLIA '88 regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

[REDACTED]

[page 3 of 6]
MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences. The analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE: Allelic loss on chromosome arm 1p is detected. Loss of one allele noted in one marker on chromosome arm 19q suggestive of partial deletion (D19S1182)

[page 4 of 6]
Informative loci are: D1S1592, D1S1612, D1S552, D19S219, D19S606 and D19S1182

Results-Comments

Testing performed on DNA extracted from tumor paraffin block
DNA extracted from a corresponding blood specimen was used as a normal reference control.

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A.

[page 5 of 6]
Brain tumor, biopsy: Glial neoplasm, with abnormal vessels and mitoses, high histological grade (astrocytic?? R/O oligodendroglioma???)
[REDACTED] Touch
preparation smears performed at [REDACTED] and results reported to the Physician of Record.

[REDACTED]

GROSS DESCRIPTION

A.

Brain tumor, biopsy

CONTAINER LABEL: tumor frozen and permanent.

FIXATIVE: Formalin. NO. PIECES: several pale gray tan fragments.

SIZE/VOL:

12 x 9 x 3 mm. in aggregate. CASSETTES: 1-FS remnant, 2-4-remainder

NS [REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates prominent gliofibrillogenesis by the neoplastic cells. The synaptophysin and NFP demonstrate overall tumor nodules partially surrounded by strands of cerebral tissue, within which there may be NeuN-positive scattered non-neoplastic neurons. The p53 protein is strongly over expressed by virtually all neoplastic cells. With the MIB-1 there is a proliferation index of about 30% throughout the tumor. The CD34 depicts a rich microvasculature with hyperplasia and microvascular cellular proliferation.

ICD-9(s):

239.6 239.6

[REDACTED]

Histo Data

Part A: Brain tumor, biopsy

Taken:	Received:	
Stain/cnt	Block	Ordered
FS H/E x 1	1	[REDACTED]
H/E x 1	1	[REDACTED]
TPS H/E x 1	1	[REDACTED]
CD34-DA x 1	2	[REDACTED]

[page 6 of 6]
EGFR vIII-curls x 1	2
mGFAP-DA x 1	2
H/E x 1	2
LOH-curls x 1	2
MGMT-curls x 1	2
MIB1-DA x 1	2
NeuN x 1	2
NF2F11 x 1	2
P53DO7 x 1	2
Synap-DA x 1	2
H/E x 1	3
H/E x 1	4

*** End of Report ***

Source: NCI Genomic Data Commons file 19145675-2a3b-4916-8526-8d8eaa569ffd (TCGA-DU-8165.611A4975-123D-470E-AFA7-4A17DBEA7A9D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).